Surgical pathology report (de-identified scan), TCGA case TCGA-D9-A149, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D9-A149-06A (Metastatic).

ICD-0-3

Malignant Melanoma, NOS

Site: Skin, NOS
C44.9

8720/3

6
11/22/10

Compliance validated by:

page 1 / 1

Department of

original

Examination: Histopathological examination

Patient: [REDACTED] PESEL: Age: Examination No.: Gender: F

Material: Lesion resection - /lesion from the left shoulder

Unit in charge:

Physician in charge:

Material collected on: Material received on:

Expected time of examination: 5 working days

Clinical diagnosis: Skin melanoma in the left shoulder region

Examination performed on:

Macroscopic description:

Skin specimen sized 10.5 x 2 x 2.5 cm with tumour in 1.5 x 1 x 1 cm found in the cross section. Minimum margin is 0.3 cm.

Examination result:

Melanoma malignum recidivans.

RECURRENT MALIGNANT MELANOMA

Compliance validated by:

Unilateral/Synchronous Primary Noted		
Assessment is Reliable		

Source: NCI Genomic Data Commons file fb7f54eb-d0d3-4e50-ba29-e2568389b5bf (TCGA-D9-A149.AE78269F-A0EB-44DE-A8AF-CDE49CC7A63E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).